Somatic mutation profile of tumor specimen TCGA-QR-A6GO-01A (aliquot TCGA-QR-A6GO-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 43.3 years (15,799 days).
Specimen TCGA-QR-A6GO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fa94f3f-4f09-42f8-a362-5a1b4d9c091a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GO-10A (Blood Derived Normal), aliquot TCGA-QR-A6GO-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba42e1cc-5695-47d2-accb-43efeb736e20

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- CACNA1A | c.5429T>G p.L1810R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC86 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LETM1 | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LTBP2 | c.5171A>C p.E1724A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.033); called by muse, mutect2
- ZNF425 | c.800_801dup p.H268Sfs*23 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
